Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8370, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8370-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]	Case ID	Gross Description	Microscopic Description
[REDACTED]	[REDACTED]	Stomach with a plate-like tumour of 8.5 cm in its largest dimension; with perigastric fat invasion; fatty tissue lymph nodes are up to 2 cm, dense, hyperemic. Omentum - hyperemia.	Adenocarcinoma of the stomach (mucin productive); G3; with superficial ulceration and adjacent fatty tissue invasion. Fifteen lymph nodes were examined, nine lymph nodes demonstrated metastases. Omentum -- focal haemorrhages.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:		STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Cardia Tumor size: 8.5 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 9/15 positive for metastasis (Greater and lesser omentum 9/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file 4e837fc9-6ce7-431d-847d-c4b067b2ba04 (TCGA-BR-8370.782E4813-0B61-4A12-8DB7-BCAE3ACE173F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).